Somatic mutation profile of tumor specimen TARGET-30-PATJZF-01A (aliquot TARGET-30-PATJZF-01A-01D) from TARGET case TARGET-30-PATJZF, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 2.8 years (1,033 days).
Specimen TARGET-30-PATJZF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ebfeae2-ea0c-4094-8045-63e5a6819d14.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATJZF-10A (Blood Derived Normal), aliquot TARGET-30-PATJZF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/462510cf-6d41-454b-8e6a-0e1a57b001bd

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, IGR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4405del p.R1469Gfs*15 (on ENST00000378444 / NM_001123385.2; = p.R1435Gfs*15 on NM_017745.6) | Frame Shift Del (DEL) | VAF 17/32 reads (53%) | catalogued as COSV60716562; called by mutect2, pindel, varscan2
- BCOR | c.4123C>T p.R1375W (on ENST00000378444 / NM_001123385.2; = p.R1341W on NM_017745.6) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV60700149; called by muse, mutect2, varscan2
- MAPKAP1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs371524490; called by muse, mutect2, varscan2
- Unknown | chr6:22020526 G>T | IGR (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
